Surgical pathology report (de-identified scan), TCGA case TCGA-74-6573, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Swedish Neurosciences, specimen TCGA-74-6573-01A (Primary Tumor).

[page 1 of 3]
Encounter Date: [REDACTED]

Results: PATHOLOGY / NON GYN
CYTOLOGY [REDACTED]

Status: [REDACTED]

TCGA-74-6573

Collection Information

Collection Date [REDACTED]

Collection Time: [REDACTED]

Lab Information

Lab [REDACTED]

Component Results

SURGICAL PATHOLOGY
REPORT

Case Number: [REDACTED]
Procedures/Addenda Present
Collected: [REDACTED] Received: [REDACTED]
Signed Out: [REDACTED] Reported: [REDACTED]

CLINICAL INFORMATION:

Malignant neoplasm of brain unspecified site.
[REDACTED]

INTRAPROCEDURAL CONSULTATION:

- A. Right lateral temporal tumor (frozen section 1 and 2 and touch preparation): Glioma, favor high-grade.
- B. Inferior temporal gyrus (frozen section and touch preparation): Glioma.
- C. Medial temporal tumor (frozen section and touch preparation): Glioblastoma.
- D. Right frontal tumor (frozen section and touch preparation): Glioblastoma.

GROSS DESCRIPTION:

- A. Received fresh labeled [REDACTED] designated "A. right lateral temporal tumor" (per requisition) is a 2.5 x 2.0 x 1.0 cm portion of white-tan brain tissue with a 1.2 x 0.5 cm granular friable focus. Two representative sections are frozen and entirely submitted in AFS1 and AFS2. The remaining specimen is entirely submitted in A1-A3.
- B. Received fresh labeled [REDACTED] designated "B. inferior temporal gyrus" is a 2.5 x 1.3 x 0.8 cm portion of tan-white brain tissue with a 1.5 x 0.7 cm granular focus on the surface. A representative section is frozen and submitted in BFS. The remaining tissue is entirely submitted in cassette B.
- C. Received fresh labeled [REDACTED] designated "C. medial temporal tumor" is a 1.5 x 1.0 x 0.6 cm aggregate of tan granular friable tissue. A representative section is frozen and submitted in CFS. The remaining tissue is entirely submitted in cassette C.
- D. Received in formalin, labeled [REDACTED] designated "D. right frontal tumor" (per requisition) is an 11.0 x 6.0 x 3.0 cm resection of partially hemorrhagic and necrotic brain tissue. The gray-light junction is well-defined. A representative section is frozen and submitted in DFS. The remaining tissue is entirely submitted in cassette D2-D16.
- E. Received in formalin labeled [REDACTED] designated "E. CUSA contents", is a 5.5 x 2.5 x 2.0 cm aggregate of multiple fragments of white partially hemorrhagic and necrotic soft tissue which is submitted entirely in cassettes E1-E3. [REDACTED]

[page 2 of 3]
FINAL PATHOLOGIC DIAGNOSIS:

A. Brain, right lateral temporal tumor:

-Diffuse glioma, favor high grade.

B. Brain, inferior temporal gyrus, resection:

-Diffuse glioma.

C. Brain, medial temporal tumor, resection; (D) Brain, right frontal tumor, resection; and (E) CUSA contents:

-Glioblastoma, WHO grade IV/IV with the following features:

-Degree of cellularity: High.

-Vascular proliferation: Present.

-Necrosis: Present.

-Mitotic rate: Up to 20 per 10 high-power fields.

-Other features:

-FISH and MGMT (by PCR) are pending.

Electronically Signed By

CONSULT:

COPY TO PHYSICIAN:

PROCEDURES/ADDENDA:

FISH Date Ordered: [REDACTED]

Status: [REDACTED]

Date Complete: [REDACTED]

By: [REDACTED]

Date Reported: [REDACTED]

Interpretation

D. Right frontal brain tumor, resection, FISH results:

-Negative for 1p/19q codeletion.

-Positive for polysomy 1 and 19.

-Positive for amplification of EGFR.

-Positive for deletion of PTEN.

Results-Comments

At the request of [REDACTED] representative sections of the tumor (block D5) were submitted for FISH analysis. The results are consistent with glioblastoma. Please see separate report by [REDACTED] (lab number [REDACTED])

TISSUE SENDOUT

Date Ordered: [REDACTED]

Status: [REDACTED]

Date Complete: [REDACTED]

By: [REDACTED]

Date Reported: [REDACTED]

Interpretation

Brain tumor, MGMT methylation studies:

-Gene methylation not detected,

[page 3 of 3]
Encounter Date: [REDACTED]

Results-Comments

At the request of [REDACTED] representative sections of the tumor were submitted to [REDACTED] for MGMT gene methylation studies by PCR. The result is gene methylation not detected. Please see separate report by [REDACTED]

ICC- IMMUNOHISTOCHEMISTRY

Date Ordered: [REDACTED]

Status: [REDACTED]

Date Complete: [REDACTED]

By: [REDACTED]

Date Reported: [REDACTED]

Interpretation

D. Brain, right frontal tumor, resection, MGMT immunohistochemistry:
-Tumor is positive for MGMT.

Results-Comments

At the request of [REDACTED] representative sections of the tumor (block D5) were submitted for MGMT by immunohistochemistry. The tumor is regionally positive (approximately 40% of overall tumor cells positive). Positive internal control (endothelial cells) are identified. [REDACTED]

[Lab Inquiry](#)

[View Complete Results](#)

[Reviewed by List](#)

Order Details

[Order Details](#)

Dept Phone: [REDACTED]

Description: [REDACTED]

Encounter: [REDACTED]

Department: [REDACTED]

Encounter

MRN [REDACTED]

Order

PATHOLOGY / NON GYN CYTOLOGY [REDACTED]

Patient Information: Patient Name Sex DOB [REDACTED]

Source: NCI Genomic Data Commons file f1bfa690-815b-43cf-b513-07b76b5f73dd (TCGA-74-6573.D33E2186-48D8-44DA-84B6-E7F88DAAC1E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).